Gene-level copy-number profile of tumor specimen TCGA-06-6695-01A from TCGA case TCGA-06-6695, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.1 years (23,426 days).
Specimen TCGA-06-6695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.7ec6b61d-88c1-4453-816b-99c754a9559c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-6695-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b2d1a57-dbab-438d-a4d4-97670bc78d1b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,993; copy number 2: 45,841; copy number 3: 7,784; copy number 5: 56; copy number 6: 39; copy number 7: 26; copy number 18: 7; copy number 20: 5; copy number 21: 3; copy number 25: 9; copy number 27: 15; copy number 29: 13; copy number 30: 12; copy number 32: 2; copy number 33: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-6695-01A-11D-1842-01): tumor purity 0.85, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 193 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,712,325–55,219,973, 48 genes, copy number 5–6: DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1.
- chr4:58,524,515–59,630,324, 10 genes, copy number 5: LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1.
- chr12:53,506,688–53,625,979, 1 gene, copy number 20 (within-gene range 1–20): ATF7-NPFF.
- chr12:53,507,856–53,626,410, 4 genes, copy number 20 (within-gene range 1–20): ATF7, AC023509.2, AC023509.6, AC023509.5.
- chr12:54,497,752–54,896,008, 10 genes, copy number 18–30: NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1.
- chr12:56,521,820–56,596,193, 2 genes, copy number 21 (within-gene range 2–21): RBMS2, RNU6-343P.
- chr12:57,194,504–57,530,148, 21 genes, copy number 7: MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6.
- chr12:57,619,527–57,896,846, 25 genes, copy number 5–25: SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr12:61,231,159–62,279,150, 6 genes, copy number 33 (within-gene range 1–33): AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19.
- chr12:64,654,060–64,655,019, 1 gene, copy number 21: AC078962.3.
- chr12:64,883,394–64,990,646, 3 genes, copy number 27 (within-gene range 1–27): LINC02389, LINC02231, RNU6ATAC42P.
- chr12:65,134,688–65,135,273, 1 gene, copy number 32: APOOP3.
- chr12:65,171,262–65,171,917, 1 gene, copy number 32: AC026124.2.
- chr12:65,466,820–66,037,714, 13 genes, copy number 29 (within-gene range 1–29): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18.
- chr12:66,347,431–68,487,863, 33 genes, copy number 6–27 (within-gene range 1–27): GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2.
- chr12:68,674,371–68,971,570, 14 genes, copy number 7–30: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 3,585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
